Somatic mutation profile of tumor specimen TCGA-QH-A6CY-01A (aliquot TCGA-QH-A6CY-01A-11D-A32B-08) from TCGA case TCGA-QH-A6CY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.7 years (14,140 days).
Specimen TCGA-QH-A6CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e0e4019-efa1-424a-980e-25637e844b44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CY-10A (Blood Derived Normal), aliquot TCGA-QH-A6CY-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f24e360b-6d37-4836-af9c-2d0679e99dfb

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4534C>A p.R1512S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50590933, COSV99360194; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD17 | c.6337G>T p.G2113* | Nonsense Mutation (SNP) | VAF 15/217 reads (7%) | catalogued as COSV100429875; called by muse, mutect2
- ARFIP2 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99601655; called by muse, mutect2, varscan2
- CCDC6 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV99569799; called by muse, mutect2, varscan2
- DSG4 | c.2515A>G p.K839E | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356355; called by muse, mutect2
- IRF7 | c.173A>C p.K58T (on ENST00000397566; = p.K45T on NM_001572.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99213335; called by mutect2, varscan2
- ITGB4 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs1288219818, COSV99564659; called by muse, mutect2, varscan2
- LYST | c.5998C>T p.L2000F | Missense Mutation (SNP) | VAF 129/391 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101090159; called by muse, mutect2, varscan2
- OR4C16 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374191202, COSV58941555; called by muse, mutect2, varscan2
- PTPN13 | c.5755G>A p.A1919T (on ENST00000411767 / NM_080683.3; = p.A1900T on NM_006264.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767268088, COSV57413226; called by muse, mutect2, varscan2
- SF3B1 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV59210744; called by muse, mutect2
- SLC7A1 | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV101060275; called by muse, mutect2, varscan2
- STPG2 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99761234; called by muse, mutect2, varscan2
- IQGAP2 | c.3036G>T p.V1012= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99167922; called by muse, mutect2, varscan2
- TRAJ22 | c.60A>G p.L20= | Silent (SNP) | VAF 143/425 reads (34%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1073G>A | Intron (SNP) | VAF 27/73 reads (37%) | catalogued as rs751150706, COSV63752956; called by muse, mutect2, varscan2
